Gene-level copy-number profile of tumor specimen HTMCP-03-06-02147-01A from CGCI case HTMCP-03-06-02147, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02147-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 30e0ef5f-1098-4143-b3e1-396d970636c4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02147-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ec3be937-33b8-40f6-80fe-a13cfc49d3c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 12,090; copy number 2: 40,533; copy number 3: 4,482; copy number 4: 320; copy number 5: 455; copy number 6: 211; copy number 7: 26; copy number 8: 80; copy number 9: 85; copy number 12: 8; copy number 13: 16; copy number 14: 17; copy number 15: 10; copy number 29: 3; copy number 34: 12; copy number 44: 3; copy number 68: 2.

Homozygous deletions (total copy number 0; autosomes only): 47 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:7,238,286–7,385,558, 15 genes: AF228730.3, OR7E125P, FAM90A15P, FAM90A3P, FAM90A4P, FAM90A13P, FAM90A5P, FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C.
- chr8:12,412,827–12,418,090, 2 genes: AC087203.3, FAM90A25P.
- chr20:14,352,320–14,352,425, 1 gene (within-gene range 0–1): RNU6-228P.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–1): RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 912 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:172,505,508–172,604,006, 4 genes, copy number 5: TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr6:30,600,413–31,158,238, 43 genes, copy number 7–15: PPP1R10, MRPS18B, ATAT1, PTMAP1, C6orf136, DHX16, PPP1R18, NRM, RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1.
- chr6:31,611,083–31,952,048, 50 genes, copy number 9 (within-gene range 1–9): UQCRHP1, AIF1, PRRC2A, SNORA38, MIR6832, BAG6, APOM, C6orf47, C6orf47-AS1, GPANK1, Y_RNA, CSNK2B, AL662899.2, LY6G5B, LY6G5C, ABHD16A, AL662899.1, MIR4646, LY6G6F, LY6G6F-LY6G6D, LY6G6E, LY6G6D, MPIG6B, LY6G6C, DDAH2, CLIC1, MSH5, MSH5-SAPCD1, RNU6-850P, SAPCD1, SAPCD1-AS1, VWA7, VARS1, Y_RNA, LSM2, HSPA1L, HSPA1A, HSPA1B, AL671762.1, SNHG32, SNORD48, SNORD52, NEU1, SLC44A4, EHMT2-AS1, EHMT2, C2, ZBTB12, AL645922.1, C2-AS1.
- chr6:32,005,636–32,178,096, 20 genes, copy number 9: CYP21A1P, TNXA, STK19B, C4B, C4B-AS1, CYP21A2, TNXB, RNA5SP206, AL662884.2, AL662884.5, ATF6B, FKBPL, PRRT1, AL662884.4, AL662884.3, PPT2, PPT2-EGFL8, EGFL8, AGPAT1, MIR6721.
- chr6:43,171,269–45,377,953, 66 genes, copy number 8–13 (within-gene range 1–13) (broad region; genes not listed).
- chr6:54,770,583–55,282,620, 6 genes, copy number 6–7: KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2.
- chr7:38,239,580–38,249,572, 1 gene, copy number 6: TRGC2.
- chr7:38,256,337–38,330,935, 13 genes, copy number 6 (within-gene range 3–6): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr10:42,149,310–42,210,383, 3 genes, copy number 9: KSR1P1, IGKV1OR10-1, AL031601.1.
- chr11:32,583,798–35,861,498, 66 genes, copy number 5–8 (broad region; genes not listed).
- chr11:39,873,782–41,459,773, 6 genes, copy number 6 (within-gene range 1–7): AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1.
- chr13:23,328,826–24,968,487, 40 genes, copy number 7–14: SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2, PCOTH, C1QTNF9B, ANKRD20A19P, AL359736.1, SPATA13, AL445985.1, IPO7P2, MIR2276, SPATA13-AS1, C1QTNF9, C1QTNF9-AS1, AL359736.2, NUS1P3, LINC00566, CYCSP33, TPTE2P6, PARP4, AL359538.4, AL359538.3, PSPC1P2, AL359538.1, ATP12A, RNY1P7, RPL26P34, IRX1P1, AL391560.2, ANKRD20A10P, RNF17, CENPJ, TPTE2P1, AL354798.1, SLC25A15P3.
- chr14:22,132,553–22,494,883, 49 genes, copy number 6: TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44.
- chr14:22,547,506–22,552,156, 1 gene, copy number 6: TRAC.
- chr17:53,353,427–53,439,721, 3 genes, copy number 5: AC005341.1, AC090079.1, AC090079.2.
- chr17:62,699,244–79,088,599, 481 genes, copy number 5–6 (broad region; genes not listed).
- chr18:45,034–1,310,018, 38 genes, copy number 6 (within-gene range 2–6): AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1.
- chr18:3,025,069–3,478,978, 17 genes, copy number 34–68: AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:3,878,058–3,897,069, 3 genes, copy number 29 (within-gene range 4–29): DLGAP1-AS3, MIR6718, RNU6-831P.
- chr20:16,177,933–16,259,603, 2 genes, copy number 5: AL161941.1, PPIAP17.

Autosomal genes at a single copy (total copy number 1): 10,998. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
